Somatic mutation profile of tumor specimen TCGA-EJ-5506-01A (aliquot TCGA-EJ-5506-01A-01D-1576-08) from TCGA case TCGA-EJ-5506, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.4 years (24,617 days).
Specimen TCGA-EJ-5506-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fa576be-1656-41fa-8fce-3f82b68f095d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5506-10A (Blood Derived Normal), aliquot TCGA-EJ-5506-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/449fcd7c-1dc1-449e-b425-b707d1ffe0a3

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHTKD1 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53802336; called by muse, mutect2
- PCDHA10 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.02); catalogued as rs781975666, COSV56485061; called by muse, mutect2, varscan2
- PCDHGA2 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 16/323 reads (5%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.012); catalogued as COSV53903734; called by muse, mutect2
